Somatic mutation profile of tumor specimen 0DB9O5 from CCDI case PBBKUF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myofibroma; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 3.7 years (1,335 days).
Specimen 0DB9O5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b78f0c1-e9e0-40bc-8db8-d8a0ec1e3cb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB9NU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12d69c07-e697-47a6-bd81-c94468e94a1e

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, In Frame Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LDHC | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 62/742 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs184986131, COSV55005168; called by muse, mutect2
- PDGFRB | c.1615_1616insGGA p.L539delinsRM | In Frame Ins (INS) | VAF 89/465 reads (19%) | called by mutect2, pindel, varscan2
- ZBTB2 | c.1049A>G p.E350G | Missense Mutation (SNP) | VAF 69/596 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- FKBP1A | c.-63C>G | 5'UTR (SNP) | VAF 35/173 reads (20%) | called by muse, mutect2, varscan2
